Gene-level copy-number profile of tumor specimen TCGA-E1-5304-01A from TCGA case TCGA-E1-5304, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 42.4 years (15,481 days).
Specimen TCGA-E1-5304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.b3e81f86-af7e-4e28-badb-66778138cc58.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-5304-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f7f87b2-871b-4f25-b199-74e051a77f8b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 755; copy number 2: 7,595; copy number 3: 21,304; copy number 4: 23,598; copy number 5: 5,813; copy number 6: 234; copy number 7: 200; copy number 8: 120; copy number 9: 69; copy number 12: 42; copy number 22: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-5304-01A-01D-1466-01): tumor purity 0.93, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 175 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:22,139,247–22,213,761, 3 genes, copy number 9: AC139497.1, PMCHL1, AC138854.1.
- chr10:44,793,119–46,030,714, 44 genes, copy number 22 (within-gene range 3–22): TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1, ALOX5, AL731567.1, MARCHF8, ZFAND4, AGAP10P, FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4.
- chr10:102,591,524–103,090,222, 20 genes, copy number 22 (within-gene range 3–22): RNU6-43P, AL391121.1, TRIM8, ARL3, SFXN2, WBP1L, RNU6-1231P, CYP17A1, PFN1P11, PTGES3P4, AL358790.1, BORCS7, BORCS7-ASMT, U6, AS3MT, RPL22P17, AL356608.3, AL356608.1, CNNM2, AL356608.2.
- chr12:1,529,891–5,946,232, 108 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 682. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
